Somatic mutation profile of tumor specimen ALCH-B2AF-TTP1-A (aliquot ALCH-B2AF-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B2AF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.2 years (24,919 days).
Specimen ALCH-B2AF-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d10c76d-cff2-4739-8149-906c4b8389cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2AF-NB1-A (Blood Derived Normal), aliquot ALCH-B2AF-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/204efbaa-eb4d-456b-ab09-38d3bbb669bc

The open-access MAF lists 107 somatic variants for this specimen: 72 protein-altering or splice-affecting, 24 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 24, Intron 6, Nonsense Mutation 4, 3'UTR 2, RNA 1, 3'Flank 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTNL3 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 50/336 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200172568, COSV61565484; called by muse, mutect2
- CCDC168 | c.5990C>T p.S1997L | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.865); catalogued as rs1158110252, COSV70555104, COSV70555375; called by muse, mutect2
- CDC42BPG | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT tolerated (0.95); PolyPhen benign (0.196); catalogued as rs956188127; called by muse, mutect2
- CDH18 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV56947923; called by muse, mutect2
- CEP295NL | c.1202T>C p.L401P | Missense Mutation (SNP) | VAF 125/414 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs1219471072; called by muse, mutect2, varscan2
- CEP350 | c.3525G>C p.K1175N | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.164); catalogued as COSV62601071; called by muse, mutect2
- CHD9 | c.3626G>A p.R1209H | Missense Mutation (SNP) | VAF 99/334 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs763711474; called by muse, mutect2, varscan2
- DARS1 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV99927834; called by muse, mutect2, varscan2
- DCST1 | c.1049C>A p.T350K | Missense Mutation (SNP) | VAF 36/522 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs555941573; called by muse, mutect2
- HNF1A | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 40/506 reads (8%) | catalogued as CM056410, COSV56567016; called by muse, mutect2
- KHDRBS3 | c.533C>G p.S178* | Nonsense Mutation (SNP) | VAF 18/533 reads (3%) | catalogued as COSV100878527; called by muse, mutect2
- LAMC3 | c.4196G>C p.R1399T | Missense Mutation (SNP) | VAF 21/532 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.119); catalogued as COSV100736131; called by muse, mutect2
- LGR6 | c.2659C>T p.R887W (on ENST00000367278 / NM_001017403.1; = p.R835W on NM_021636.3) | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs140402059, COSV55161004; called by muse, mutect2, varscan2
- NFXL1 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs1002335894; called by muse, mutect2
- NIPBL | c.211C>G p.Q71E | Missense Mutation (SNP) | VAF 118/496 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs780649689; called by muse, mutect2, varscan2
- NLRP5 | c.1229G>C p.R410T | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.838); catalogued as COSV66762791, COSV66767825; called by muse, mutect2
- ODF3L2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.095); catalogued as rs1043189275; called by muse, mutect2
- OR7C2 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 25/563 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.114); catalogued as COSV50180492; called by muse, mutect2
- PLCG2 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs369760877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA6 | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 152/569 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs527810742; called by muse, mutect2, varscan2
- PRPF3 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 18/498 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as rs201882091, COSV61396614; called by muse, mutect2
- PTCHD3 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 47/705 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1351637148, COSV71256494; called by muse, mutect2
- RPN1 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs746362304; called by muse, varscan2
- RPS6KL1 | c.639C>G p.I213M | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63580612; called by muse, mutect2
- SEMA5B | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 106/256 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.34); catalogued as rs147395298; called by muse, mutect2, varscan2
- SYNE2 | c.5591C>G p.S1864* | Nonsense Mutation (SNP) | VAF 20/542 reads (4%) | catalogued as COSV59944430; called by muse, mutect2
- TP53 | c.477del p.M160Wfs*10 | Frame Shift Del (DEL) | VAF 69/224 reads (31%) | catalogued as COSV52713618; called by mutect2, pindel, varscan2
- URB2 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1349140717; called by muse, mutect2
- ZNF496 | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 79/421 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs138760260; called by muse, mutect2, varscan2
- AREL1 | c.313G>T p.V105F | Missense Mutation (SNP) | VAF 18/530 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.299); called by muse, mutect2
- ATG2A | c.3421C>G p.L1141V | Missense Mutation (SNP) | VAF 137/471 reads (29%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C11orf95 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- CCT5 | c.243G>C p.M81I | Missense Mutation (SNP) | VAF 58/505 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CD7 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.736); called by muse, mutect2
- CDR2 | c.1020G>C p.Q340H | Missense Mutation (SNP) | VAF 118/467 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- CPD | c.2609T>G p.L870R | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD2 | c.9796G>A p.A3266T | Missense Mutation (SNP) | VAF 81/472 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTC1 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- CXXC1 | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 16/358 reads (4%) | called by muse, mutect2
- DCAF12L2 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 26/459 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCLRE1A | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.091); called by muse, mutect2
- DYNC1H1 | c.2032G>C p.E678Q | Missense Mutation (SNP) | VAF 12/301 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- EIF2B5 | c.888C>G p.H296Q (on ENST00000647909; = p.H288Q on NM_003907.3) | Missense Mutation (SNP) | VAF 191/490 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- FLI1 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GOLGA6L7 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 125/412 reads (30%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- JAKMIP2 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- KDR | c.2651C>T p.S884F | Missense Mutation (SNP) | VAF 147/429 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL35 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- LRRC53 | c.467T>C p.L156P | Missense Mutation (SNP) | VAF 46/564 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2
- LYNX1-SLURP2 | c.218G>T p.R73I | Missense Mutation (SNP) | VAF 18/438 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2
- MAP3K2 | c.1700T>G p.M567R | Missense Mutation (SNP) | VAF 30/581 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- MEPE | c.1237C>T p.H413Y | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- NCAPH2 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 46/664 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.354); called by muse, mutect2
- OR4K17 | c.540C>G p.D180E | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDZD2 | c.6429T>A p.H2143Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PHKB | c.2486G>C p.R829T | Missense Mutation (SNP) | VAF 16/345 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- RASA1 | c.1620T>G p.C540W | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR2 | c.3985G>T p.G1329W | Missense Mutation (SNP) | VAF 27/424 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2
- SAMD9 | c.624A>T p.E208D | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, varscan2
- SLC25A13 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 99/432 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC6A18 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 73/315 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SV2A | c.1853T>A p.L618H | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- TECTA | c.4606G>T p.A1536S | Missense Mutation (SNP) | VAF 18/566 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TMOD3 | c.771G>C p.L257F | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TOR1B | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 62/372 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- TRANK1 | c.1013T>C p.V338A | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- TTN | c.10483G>C p.D3495H (on ENST00000591111; = p.D3449H on NM_003319.4) | Missense Mutation (SNP) | VAF 12/398 reads (3%) | called by muse, mutect2
- UNC50 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- UNKL | c.170T>G p.F57C | Missense Mutation (SNP) | VAF 87/382 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WAC | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF354A | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 10/271 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- ZNF837 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2
- ANK3 | c.9765C>T p.P3255= | Silent (SNP) | VAF 7/136 reads (5%) | called by muse, mutect2
- BTBD7 | c.1170G>A p.E390= | Silent (SNP) | VAF 14/232 reads (6%) | called by muse, mutect2
- CCDC114 | c.1239C>A p.L413= | Silent (SNP) | VAF 14/392 reads (4%) | called by muse, mutect2
- DHX35 | c.570C>T p.G190= | Silent (SNP) | VAF 65/374 reads (17%) | catalogued as rs373143584; called by muse, varscan2
- ENPEP | c.354C>T p.T118= | Silent (SNP) | VAF 24/798 reads (3%) | catalogued as rs1221633835; called by muse, mutect2
- EXTL3 | c.2256C>T p.D752= | Silent (SNP) | VAF 31/584 reads (5%) | catalogued as rs781276373, COSV55037022; called by muse, mutect2
- FASN | c.2406G>A p.R802= | Silent (SNP) | VAF 36/688 reads (5%) | catalogued as rs1485251700; called by muse, mutect2
- GPA33 | c.210C>T p.V70= | Silent (SNP) | VAF 32/270 reads (12%) | catalogued as rs149134521; called by muse, mutect2, varscan2
- IER3 | c.198C>G p.L66= | Silent (SNP) | VAF 19/584 reads (3%) | catalogued as rs1414455853; called by muse, mutect2
- MTR | c.264T>G p.A88= | Silent (SNP) | VAF 25/633 reads (4%) | called by muse, mutect2
- PDZD4 | c.1869G>A p.E623= | Silent (SNP) | VAF 7/154 reads (5%) | called by muse, mutect2
- RNGTT | c.696C>T p.F232= | Silent (SNP) | VAF 11/237 reads (5%) | catalogued as rs926841055; called by muse, mutect2
- RPGRIP1L | c.2022G>A p.Q674= | Silent (SNP) | VAF 10/210 reads (5%) | called by muse, mutect2
- RPL10 | c.528C>T p.F176= | Silent (SNP) | VAF 26/972 reads (3%) | catalogued as rs782301289; called by muse, mutect2
- SAFB2 | c.1269C>G p.L423= | Silent (SNP) | VAF 16/356 reads (4%) | called by muse, mutect2
- SBF1 | c.3483C>T p.I1161= | Silent (SNP) | VAF 34/167 reads (20%) | called by muse, mutect2, varscan2
- SPTAN1 | c.1950A>G p.A650= | Silent (SNP) | VAF 21/742 reads (3%) | called by muse, mutect2
- SSTR5 | c.456C>A p.R152= | Silent (SNP) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- TCEAL6 | c.303G>A p.P101= | Silent (SNP) | VAF 12/289 reads (4%) | called by muse, mutect2
- TMC5 | c.993C>G p.V331= | Silent (SNP) | VAF 22/353 reads (6%) | catalogued as COSV66869349; called by muse, mutect2
- TRAPPC12 | c.1263G>A p.T421= | Silent (SNP) | VAF 30/542 reads (6%) | catalogued as rs547835457; called by muse, mutect2
- TTN | c.52356G>A p.Q17452= (on ENST00000591111; = p.Q10028= on NM_003319.4) | Silent (SNP) | VAF 134/403 reads (33%) | called by muse, mutect2, varscan2
- VMAC | c.54C>T p.A18= | Silent (SNP) | VAF 38/267 reads (14%) | catalogued as rs1193410979; called by muse, mutect2, varscan2
- ZNF648 | c.1512C>T p.F504= | Silent (SNP) | VAF 24/339 reads (7%) | called by muse, mutect2
- CBFA2T2 | c.62-6544T>C | Intron (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2
- CHRNA4 | c.*44G>T | 3'UTR (SNP) | VAF 25/487 reads (5%) | called by muse, mutect2
- COL9A3 | c.147+225C>T | Intron (SNP) | VAF 18/58 reads (31%) | catalogued as rs1033609529; called by muse, mutect2, varscan2
- GRAMD1B | c.1085-53C>T | Intron (SNP) | VAF 38/762 reads (5%) | catalogued as rs1248543263; called by muse, mutect2
- LINC02145 | n.472C>A | RNA (SNP) | VAF 10/34 reads (29%) | called by mutect2, varscan2
- POTEM | c.811-1248G>A | Intron (SNP) | VAF 97/1190 reads (8%) | catalogued as rs765476233; called by muse, mutect2, varscan2
- RAB11B | chr19:8390352 C>A | 5'Flank (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- SNORD116-22 | chr15:25092297 G>A | 3'Flank (SNP) | VAF 39/371 reads (11%) | catalogued as rs373381759; called by muse, mutect2, varscan2
- SPEG | c.*158G>A | 3'UTR (SNP) | VAF 22/550 reads (4%) | called by muse, mutect2
- TRIM61 | c.526-2217C>G | Intron (SNP) | VAF 25/821 reads (3%) | called by muse, mutect2
- ZEB2 | c.73+3497G>A | Intron (SNP) | VAF 29/648 reads (4%) | catalogued as rs1173538677; called by muse, mutect2
